CCDI case PBBWKM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/996cb1cf-935f-4a79-9caa-01033edad8de

Demographics
Sex at birth: female.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.5 years (3,468 days).

Biospecimens (3 samples)
- Sample 0DJHDZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJHEF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJHH5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
